Somatic mutation profile of tumor specimen TCGA-DK-A2I2-01A (aliquot TCGA-DK-A2I2-01A-11D-A17V-08) from TCGA case TCGA-DK-A2I2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.3 years (23,116 days).
Specimen TCGA-DK-A2I2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0a8c086-4a86-4c36-baac-940a42b821cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A2I2-10A (Blood Derived Normal), aliquot TCGA-DK-A2I2-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbbd11fc-3b35-4c62-87e6-a9275afabf2c

The open-access MAF lists 100 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 26, Nonsense Mutation 7, Intron 1, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 26/114 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ACTL6A | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66999477; called by muse, mutect2
- ADPRM | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV59380160; called by muse, mutect2, varscan2
- ALDOA | c.742G>A p.D248N (on ENST00000642816 / NM_001243177.4; = p.D194N on NM_184041.5) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV57633995; called by mutect2, varscan2
- ALK | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV66588949; called by muse, mutect2, varscan2
- ARHGEF17 | c.4795C>T p.L1599F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV55237929; called by muse, mutect2, varscan2
- ASS1 | c.945G>C p.L315F | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV61690676; called by muse, mutect2
- ATAD2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV54886496; called by muse, mutect2, varscan2
- C1QTNF7 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs776448155, COSV54856211; called by muse, mutect2, varscan2
- CFAP61 | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV55624639, COSV55646990; called by muse, mutect2, varscan2
- COL23A1 | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs960664519; called by muse, mutect2
- COL5A2 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as rs747653593, COSV66415038; ClinVar: uncertain significance; called by mutect2, varscan2
- COL6A6 | c.4355G>T p.G1452V | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62036914; called by muse, mutect2, varscan2
- CPEB3 | c.1076C>G p.T359S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV56462887; called by muse, mutect2, varscan2
- DFFA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV65478232, COSV65478295; called by muse, mutect2, varscan2
- DIS3L2 | c.2090C>T p.T697I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56063294; called by mutect2, varscan2
- DLC1 | c.3953C>T p.S1318L (on ENST00000276297 / NM_001348081.2; = p.S881L on NM_006094.5) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1319513394, COSV52327219; called by mutect2, varscan2
- EEF2K | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV53783297, COSV53785767; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2113A>G p.M705V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57518034; called by muse, mutect2, varscan2
- EMD | c.450-1G>A p.X150_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | catalogued as COSV63962500; called by muse, mutect2, varscan2
- ERI3 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as rs1179164014, COSV64833640; called by muse, mutect2
- FAM171A1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV65319991; called by muse, mutect2, varscan2
- FBXW7 | c.2033C>G p.S678* (on ENST00000281708 / NM_001349798.2; = p.S598* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 53/109 reads (49%) | catalogued as COSV55897853; called by muse, mutect2, varscan2
- FHOD1 | c.3422C>T p.T1141M | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762626115, COSV50769239; called by mutect2, varscan2
- FIGNL1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63554050, COSV63554065; called by muse, varscan2
- FLG | c.3323G>A p.G1108E | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs759217139, COSV64248739; called by muse, mutect2, varscan2
- FRMPD4 | c.3565C>A p.R1189S | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV66221812, COSV66223127; called by muse, mutect2, varscan2
- FSTL4 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54785453; called by muse, mutect2, varscan2
- GALR1 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV55319048; called by muse, varscan2
- GFM1 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV51835694, COSV51835804; called by muse, mutect2, varscan2
- GLT1D1 | c.778G>A p.E260K (on ENST00000442111 / NM_001366889.1; = p.E180K on NM_144669.3) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55887551, COSV99897584; called by muse, mutect2, varscan2
- GRID2 | c.439C>G p.R147G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56194154, COSV56263799; called by muse, mutect2, varscan2
- H2BC7 | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as COSV61912395; called by muse, mutect2, varscan2
- KDM6A | c.3579G>A p.W1193* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV65046872; called by muse, mutect2, varscan2
- KDM6B | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV54683999; called by muse, varscan2
- KLHDC8B | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV60412767; called by muse, mutect2, varscan2
- KRBA1 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs767107569, COSV55444225; called by mutect2, varscan2
- MX1 | c.1509G>A p.K503= | Splice Region (SNP) | VAF 134/405 reads (33%) | catalogued as COSV55820871; called by muse, mutect2, varscan2
- NBR1 | c.174C>G p.I58M | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV57835464; called by muse, mutect2
- NCAPD2 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766002564, COSV57520849; called by muse, mutect2, varscan2
- NCOR1 | c.3068G>C p.R1023P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV51995614; called by muse, mutect2, varscan2
- NETO2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57455604; called by mutect2, varscan2
- OR8J1 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV57320053; called by muse, mutect2, varscan2
- PCDHGA3 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); catalogued as COSV54056886; called by mutect2, varscan2
- PDIA3 | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55858280; called by mutect2, varscan2
- PIK3CB | c.54G>A p.W18* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100006157; called by muse, mutect2, varscan2
- PIP4K2A | c.1058A>T p.Y353F | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV60542618; called by muse, mutect2, varscan2
- PTK6 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV53918471; called by muse, mutect2, varscan2
- RAG2 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 21/440 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.172); catalogued as COSV57559730; called by muse, mutect2
- RASA1 | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57199839; called by muse, mutect2, varscan2
- RELN | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59032945; called by muse, mutect2
- RIMS2 | c.3938C>T p.S1313F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV104385565, COSV99155694; called by mutect2, varscan2
- RNF213 | c.7276A>G p.K2426E | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60398381; called by muse, mutect2, varscan2
- S100PBP | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV63140636; called by muse, mutect2, varscan2
- S1PR1 | c.823C>G p.L275V | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV59514511; called by muse, mutect2, varscan2
- SESN3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53587389; called by muse, mutect2, varscan2
- SLC37A3 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58268476; called by muse, mutect2
- STX3 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs140824363, COSV100275720; called by muse, mutect2, varscan2
- TBL2 | c.391A>G p.R131G | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59788295; called by muse, mutect2
- TEP1 | c.403C>G p.H135D | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52989140; called by muse, mutect2
- TRAT1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV55470849; called by muse, mutect2, varscan2
- UVSSA | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs551571397, COSV66230911; called by muse, varscan2
- ZNF451 | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as rs1315145972, COSV62599994; called by mutect2, varscan2
- ECI2 | c.993G>A p.W331* (on ENST00000380118 / NM_206836.3; = p.W301* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- G2E3 | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HAUS3 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by mutect2, varscan2
- ITPR2 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- KDM3B | c.826dup p.R276Kfs*21 | Frame Shift Ins (INS) | VAF 12/130 reads (9%) | called by mutect2, pindel
- MYEF2 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, varscan2
- SMARCE1 | c.477_482del p.R160_Q161del | In Frame Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- SYBU | c.590C>A p.S197* (on ENST00000276646 / NM_001099754.2; = p.S196* on NM_017786.6) | Nonsense Mutation (SNP) | VAF 20/160 reads (13%) | called by mutect2, varscan2
- TOR2A | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | called by muse, mutect2, varscan2
- ATP9A | c.2796C>T p.I932= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV58771714; called by muse, mutect2, varscan2
- BRPF3 | c.234G>A p.K78= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV60209711; called by muse, mutect2, varscan2
- CDC42BPA | c.1452C>T p.S484= | Silent (SNP) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- CTTNBP2NL | c.657A>G p.E219= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV54746835; called by muse, mutect2, varscan2
- ENPP2 | c.2217C>T p.F739= (on ENST00000075322 / NM_001040092.3; = p.F791= on NM_006209.5) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs547371219, COSV99309615; called by mutect2, varscan2
- EPB41 | c.1647C>A p.V549= (on ENST00000343067 / NM_001166005.2; = p.V340= on NM_004437.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs145888614, COSV58053936; called by muse, mutect2, varscan2
- GALNTL6 | c.507G>A p.G169= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV71831715; called by muse, mutect2, varscan2
- GBP5 | c.1188G>A p.R396= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as rs267598755, COSV58594310; called by muse, mutect2, varscan2
- GON4L | c.6255G>A p.V2085= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as rs1296740452, COSV55189112; called by mutect2, varscan2
- HEPHL1 | c.546G>C p.L182= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- IGSF1 | c.2508C>A p.I836= | Silent (SNP) | VAF 55/565 reads (10%) | catalogued as COSV63838365, COSV63840222; called by muse, mutect2, varscan2
- KLHL1 | c.433C>T p.L145= | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV64783563; called by muse, mutect2, varscan2
- MLIP | c.1293C>T p.L431= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV51436849; called by muse, mutect2, varscan2
- OR2M2 | c.903C>T p.F301= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV62899389; called by mutect2, varscan2
- PON2 | c.414T>C p.N138= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV56003546; called by muse, mutect2, varscan2
- SEMA4C | c.981G>A p.S327= | Silent (SNP) | VAF 20/208 reads (10%) | catalogued as rs914866875, COSV59692253; called by muse, mutect2
- SGO1 | c.255G>A p.L85= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV55425274; called by muse, mutect2
- SH3BP2 | c.681C>T p.T227= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV62555363; called by muse, mutect2, varscan2
- SLC25A40 | c.681A>G p.K227= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV62021660; called by muse, mutect2, varscan2
- STX11 | c.681C>G p.L227= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV62449010; called by muse, mutect2, varscan2
- TEX2 | c.2559C>A p.L853= (on ENST00000583097 / NM_001288733.2; = p.L860= on NM_018469.5) | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as COSV51985455; called by muse, mutect2, varscan2
- THRA | c.801C>T p.Y267= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs371948181; called by mutect2, varscan2
- TMC7 | c.1722C>T p.I574= | Silent (SNP) | VAF 42/389 reads (11%) | catalogued as rs1246459896, COSV58582924, COSV58587723; called by muse, mutect2, varscan2
- TRANK1 | c.8457A>G p.V2819= | Silent (SNP) | VAF 50/212 reads (24%) | catalogued as COSV57163644; called by muse, mutect2, varscan2
- UNC13C | c.3918T>C p.D1306= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV52922408; called by muse, mutect2, varscan2
- XKR6 | c.1626G>A p.T542= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs201850605; called by mutect2, varscan2
- ATP8A1 | c.451-3447G>T | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as COSV52547702; called by muse, mutect2, varscan2
- NFATC4 | chr14:24367114 C>T | 5'Flank (SNP) | VAF 24/190 reads (13%) | catalogued as COSV51610924; called by mutect2, varscan2
